TCGA case TCGA-VQ-AA68 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3ff9b46b-325f-4655-ab40-953154753dae

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 52 years; Vital status: Alive.

Diagnoses (1)
1. Tubular adenocarcinoma: ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 52.9 years (19,304 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,328 days (3.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 21; Lymph nodes tested: 27.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 152 days; Days to treatment end: 324 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 194 days; Days to treatment end: 238 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.

Follow-up (2 entries)
- Days to follow up: 1,219 days (3.3 years); Disease response: Tumor Free.
- Days to follow up: 1,328 days (3.6 years); Disease response: Tumor Free.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-AA68-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-VQ-AA68-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-VQ-AA68-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-AA68-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Gastroesophageal Junction; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,328 days; disease-specific survival: no event (censored), 1,328 days; disease-free interval: no event (censored), 1,328 days; progression-free interval: no event (censored), 1,328 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-AA68-01A-11D-A40Z-01): tumor purity 0.33, ploidy 6.01, whole-genome doublings 2.
